CGCI case HTMCP-01-10-00769 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d9b37433-dd78-480c-a242-0fdf623830af

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 63.3 years (23,127 days); Year of diagnosis: 2014; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage IV; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,164 days (5.9 years); Ann Arbor extranodal involvement: Yes; Sites of involvement: Kidney, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Parotid.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (5 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 888 days (2.4 years); Disease response: Tumor Free.
- Days to follow up: 1,818 days (5.0 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Positive.
- Days to follow up: 2,164 days (5.9 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Positive.
- Follow-up contact recording only the day: day 42.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (Flow Cytometry): Negative.
- BCL2 (IHC): Negative.
- BCL6 (FISH): Normal.
- BCL6 (Flow Cytometry): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (Flow Cytometry): Positive; Specialized molecular test: CD10 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD138 (Flow Cytometry): Equivocal.
- CD19 (Flow Cytometry): Positive.
- CD20 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD22 (Flow Cytometry): Equivocal.
- CD23 (Flow Cytometry): Negative.
- CD3 (IHC): Negative.
- CD30 (Flow Cytometry): Equivocal.
- CD5 (Flow Cytometry): Positive.
- CD79A (Flow Cytometry): Equivocal.
- CD79A (IHC): Positive.
- IRF4 (Flow Cytometry): Negative; Specialized molecular test: MUM1 > 30%.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC (FISH): Normal.
- PAX5 (Flow Cytometry): Positive.
- TP53 (Flow Cytometry): Equivocal; Specialized molecular test: P53 > 20%.
- TP53 (IHC): Negative; Specialized molecular test: P53 > 20%.
- Test (Flow Cytometry): Equivocal; Specialized molecular test: Cytoplasmic Ig.
- Test (Flow Cytometry): Negative; Specialized molecular test: EBER.
- Test (Flow Cytometry): Negative; Specialized molecular test: HHV8.
- Test (Flow Cytometry): Positive; Specialized molecular test: Surface Ig.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 353 [Blood test normal range upper: 271].

Other clinical attributes
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Weight: 107.95 kg; Height: 175 cm; BMI: 35.2; CD4 count: 69; Haart treatment indicator: No; HIV viral load: 102000.
- Day 42: Risk factors: HIV/AIDS.
- Day 42: Comorbidities: HIV/AIDS.
- Day 888: Nadir CD4 count: 40.

Biospecimens (3 samples)
- Sample HTMCP-01-10-00769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-10-00769-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-10-00769-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: No; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Kidney.
- Primary pathology: Extranodal site involvement: 1; Method initial path diagnosis: Biopsy (all types); Days from index date to tumor sample procurement: 21.
- Tests performed: LDH level: 353; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: P53 >20%; Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD138; Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: CD22; Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunophenotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunophenotypic analysis tested: CD79a; Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunophenotypic analysis tested: PAX5.
- Tests performed, Genetic testing results, Genetic testing result 13: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 14: Immunophenotypic analysis tested: HHV8.
- Tests performed, Genetic testing results, Genetic testing result 15: Immunophenotypic analysis tested: CD30; Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic testing results, Genetic testing result 18: Immunophenotypic analysis tested: Eber.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-10-00769-01A-01E-12504:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-10-00769-01A-01S-12504:
- % tumour top: 80
- % tumour bottom: 80
